Somatic mutation profile of tumor specimen C3N-03448-01 (aliquot CPT0225870006) from CPTAC case C3N-03448, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.8 years (25,144 days).
Specimen C3N-03448-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) faaae54c-3203-4d24-8a9b-45020313480d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03448-31 (Blood Derived Normal), aliquot CPT0225890002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df4c07a1-8871-45d7-9a1d-9246c122926d

The open-access MAF lists 35 somatic variants for this specimen: 27 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 4, RNA 2, Frame Shift Del 1, 5'UTR 1, Splice Site 1, Frame Shift Ins 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.635-1G>A p.X212_splice | Splice Site (SNP) | VAF 39/229 reads (17%) | hotspot (GDC flag); catalogued as rs876661024, CS090867, CS993675, COSV64289221, COSV64292432, COSV64296169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.820G>C p.V274L | Missense Mutation (SNP) | VAF 112/741 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs1057520005, COSV52707923, COSV52708386, COSV52728497, COSV53727597; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.455C>G p.P152R | Missense Mutation (SNP) | VAF 35/272 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; called by muse, mutect2, varscan2
- ATG2A | c.2849G>A p.R950Q | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs772008010; called by muse, mutect2, varscan2
- CEP170B | c.2089C>T p.R697C (on ENST00000453495; = p.R626C on NM_015005.3) | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs989439867; called by muse, mutect2, varscan2
- DAG1 | c.875A>G p.Y292C | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1422604975; called by muse, mutect2, varscan2
- IL31RA | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 81/306 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.058); catalogued as rs780594680, COSV51685891; called by muse, mutect2, varscan2
- KIF1B | c.3271A>G p.S1091G (on ENST00000377086 / NM_001365952.1; = p.S1045G on NM_015074.3) | Missense Mutation (SNP) | VAF 45/335 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs753279755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MED12 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 56/295 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61334558; called by muse, mutect2, varscan2
- MRGPRX4 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 38/322 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs778327061, COSV58589894; called by muse, mutect2, varscan2
- MSLNL | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.066); catalogued as rs746495910, COSV53501725; called by muse, mutect2, varscan2
- MUC17 | c.7370C>T p.P2457L | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs147089389; called by muse, mutect2, varscan2
- PKHD1 | c.3839G>A p.R1280H | Missense Mutation (SNP) | VAF 68/409 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374233100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKX | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 69/550 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1214483066; called by muse, mutect2, varscan2
- RB1 | c.2391dup p.R798Tfs*17 | Frame Shift Ins (INS) | VAF 37/231 reads (16%) | catalogued as CI012716, COSV57300252, COSV57321960; called by mutect2, pindel, varscan2
- TAF7 | c.671A>G p.N224S | Missense Mutation (SNP) | VAF 75/223 reads (34%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.985); catalogued as rs1418463379; called by muse, mutect2, varscan2
- TICRR | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs746440485, COSV51537264; called by muse, mutect2, varscan2
- ABCC5 | c.2649G>C p.W883C | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACVR2A | c.165del p.D55Efs*19 | Frame Shift Del (DEL) | VAF 37/315 reads (12%) | called by mutect2, pindel, varscan2
- ADGRE1 | c.817C>G p.R273G | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- BAZ2B | c.1216C>G p.P406A | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CDH5 | c.246C>A p.Y82* | Nonsense Mutation (SNP) | VAF 26/129 reads (20%) | called by muse, mutect2
- NDUFAF5 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 86/655 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NOS3 | c.1237G>C p.A413P | Missense Mutation (SNP) | VAF 48/338 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC35F6 | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 70/435 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMC1A | c.2875G>C p.G959R | Missense Mutation (SNP) | VAF 52/428 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TES | c.1004T>A p.L335Q | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BARD1 | c.1881A>G p.G627= | Silent (SNP) | VAF 33/255 reads (13%) | catalogued as rs968535447; ClinVar: likely benign; called by muse, mutect2, varscan2
- DGKH | c.1236G>A p.L412= | Silent (SNP) | VAF 17/140 reads (12%) | called by muse, mutect2, varscan2
- OR10P1 | c.231C>T p.I77= | Silent (SNP) | VAF 32/223 reads (14%) | catalogued as rs541088749, COSV59007194, COSV59008648; called by muse, mutect2, varscan2
- RASA3 | c.2214C>T p.N738= | Silent (SNP) | VAF 34/173 reads (20%) | called by muse, mutect2, varscan2
- GRIN3A | c.-43C>A | 5'UTR (SNP) | VAF 53/360 reads (15%) | called by muse, mutect2, varscan2
- KIF28P | n.1960T>C | RNA (SNP) | VAF 60/332 reads (18%) | called by muse, mutect2, varscan2
- MSL3 | c.102+389G>A | Intron (SNP) | VAF 52/394 reads (13%) | catalogued as rs1327293608; called by muse, mutect2, varscan2
- TBC1D3P1 | n.79C>T | RNA (SNP) | VAF 52/513 reads (10%) | catalogued as rs764198513; called by muse, mutect2, varscan2
